Gene-level copy-number profile of tumor specimen TCGA-12-0773-01A from TCGA case TCGA-12-0773, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 24.2 years (8,849 days).
Specimen TCGA-12-0773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.23d84686-9d9e-497f-8822-e56bd5a6dbec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0773-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09e60c94-1864-417b-b0e4-d4ec8a024b96

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,614; copy number 2: 48,942; copy number 3: 3,492; copy number 4: 3,579; copy number 5: 181.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0773-01A-01D-0333-01): tumor purity 0.84, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,437,028–50,960,267, 1 gene (within-gene range 0–2): FAF1.
- chr1:50,780,340–51,060,103, 5 genes: PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 181 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:142,265,833–145,681,369, 181 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
